Gene-level copy-number profile of specimen HCM-CSHL-0379-C18-85A from HCMI case HCM-CSHL-0379-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,410 days).
Specimen HCM-CSHL-0379-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74facf10-c2e8-4653-a345-c77851b3ba9b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0379-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/1b7ceeca-e76f-49f5-aaf1-36658c4832da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,720; copy number 2: 45,708; copy number 3: 6,744; copy number 4: 535; copy number 5: 46; copy number 14: 19; copy number 15: 5; copy number 18: 13; copy number 21: 116.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:81,149,107–81,284,777, 6 genes, copy number 5: AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr8:98,943,595–100,663,415, 40 genes, copy number 5: AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1.
- chr17:36,253,456–36,944,612, 19 genes, copy number 14 (within-gene range 1–14): TBC1D3I, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J, ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1.
- chr17:38,181,659–40,975,926, 134 genes, copy number 15–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
